Surgical pathology report (de-identified scan), TCGA case TCGA-ND-A4WA, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Cedars Sinai, specimen TCGA-ND-A4WA-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

PATIENT:
Hospital No.:
Date of Birth:

PATH #:
A/S: F
Rec:
Col:

Location:
Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

DIAGNOSIS: **ADDENDUM,

3. TOTAL ABDOMINAL HYSTERECTOMY:

- Malignant mixed mullerian tumor of endometrium with heterologous elements MMMT (high grade carcinosarcoma)
- Carcinomatous component: High grade serous adenocarcinoma
- Sarcomatous component: High grade endometrial stromal sarcoma
- Heterologous component: Chondrosarcoma
- Tumor dimension: 5.8 x 5.1 x 4.6 cm
- The tumor invades to greater than half of myometrium (greater than 50%)
- No endocervical or lower uterine segment invasion is identified
- Extensive vascular invasion is present
- The uninvolved endometrium is atrophic
- The myometrium shows extensive adenomyosis and three subserosal leiomyomas, one of which shows extensive calcification (the leiomyomas vary in size from 0.3 to 2.5 cm)
- The cervix shows chronic cervicitis with squamous metaplasia and leiomyoma (1.1 cm)
- The parametrium shows foci of lymphovascular space invasion but no direct invasion
- Stage: pT1c Nx Mx (based on material examined)

1. LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY:

- Left fallopian tube showing intraluminal tufts of malignant cells
- Left fallopian tube showing no direct parenchymal invasion by tumor
- Left fallopian tube also shows cystic and noncystic Walthard rests and mesonephric duct remnants
- Left ovary shows corpora albicantia and no evidence of malignancy

2. RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY:

- Right ovary showing focal surface epithelial inclusion glands and surface adhesions
- Right fallopian tube showing no significant histopathologic

(continued on next page)

Page: 2

changes

- Right adnexa free from tumor

ADDENDUM:

name was added to the "Copies To" section.

HISTORY: MMMT

MICROSCOPIC:

Deeper sections were examined on block (O) and the findings have been incorporated in the diagnosis.

100-0-3
Carcinosarcoma / Mixed Mullerian Tumor
Malignant 8956/3
Site Corpus Uteri, Endometrium C54.1
QID 3/18/13

[page 2 of 3]
GROSS:

1: LEFT ADNEXA

Labeled with the patient's name, designated "left adnexa" and received in formalin is a 4.7 cm in length and 0.4 cm in diameter fimbriated segment of fallopian tube. The serosa is tan-pink and dull with small scattered serosal serous cysts. There is a 0.1 cm lumen. There is an attached 1.7 x 1.1 x 0.7 cm ovary with a smooth tan-yellow external surface. On sectioning, cut surfaces reveal multiple corpora albicantia. No additional lesions are identified. Representative sections.

A. Fallopian tube and entire ovary - 3

2: RIGHT ADNEXA

Labeled with the patient's name, designated "right adnexa" and received in formalin is a 4.7 x 0.4 cm fimbriated segment of fallopian tube. The serosa is dull, tan-pink and smooth. On sectioning there is a 0.1 cm lumen. There is an attached 1.7 x 1.1 x 0.6 cm ovoid, smooth, tan-yellow ovary. On sectioning cut surfaces reveal multiple corpora albicantia. No additional lesions are identified. Representative sections.

B. Fallopian tube and entire ovary - 3

3: UTERUS

Labeled with the patient's name, designated "uterus", received fresh in the operating room for gross consultation and subsequently fixed in formalin is a 120-gram uterus and cervix without attached adnexa. The uterus is 7.0 cm from fundus to ectocervix, 4.2 cm from cornu to cornu, and 5.5 cm from anterior to posterior. The serosa is tan-red and dull. The cervix is 2.1 cm in length and 1.6 cm in diameter with a 0.2 cm patent os. The ectocervical mucosa is tan-red and smooth. Specimen is opened to reveal a distinct transformation zone. The endocervical canal is 1.7 cm in length and tan and rugose without obvious lesion. The endometrial cavity is 4.0 cm in length and 2.5 cm in maximum diameter. The anterior and posterior left cornu displays a 5.8 x 5.1 x 4.6 cm intramural, firm to focally friable tan-white to pink-white tumor mass. The tumor invades to greater than half of the myometrium but does not extend to the serosa. The remaining endometrium is smooth, tan-pink with a less than 0.1 cm thickness. The myometrium measures up to 2.2 cm in maximum thickness and contains three subserosal leiomyomas ranging from 0.3 to 2.5 cm in greatest dimension. The largest subserosal myoma has a diffusely calcified cut surface. The remaining cut surfaces are firm, tan-white, and whorled without areas of hemorrhage or

(continued on next page)

Page: 3

necrosis. On sectioning, the intramural mass has a diffusely softened and focally necrotic cut surface. Representative sections.

- C. Smaller subserosals myomas - 2
- D. Calcified subserosal myoma - 2
- E. Anterior corpus overlying mass - 1
- F. Anterior intramural mass - 1
- G. Anterior serosa overlying mass - 1
- H. Anterior lower uterine segment - 1
- I. Anterior cervix - 1
- J. Posterior corpus with underlying tumor - 1
- K. Posterior intramural tumor - 1
- L. Posterior serosa overlying intramural tumor - 1
- M. Posterior lower uterine segment - 1
- N. Posterior cervix - 1
- O. Parametrial soft tissue - 2
- P-W. Additional sections of tumor - 1 each

[page 3 of 3]
Gross dictated by

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

Specimen #3: Uterus:

- Previously opened uterus revealing necrotic endometrial neoplasm contiguous with a leiomyoma-like mass which contains chondroid or osseous-like area grossly; suspicious for deep myometrial invasion, defer to microscopic examination for definitive depth of invasion

Special Studies: None

See Also:

Pathologist

I, _____ the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled: _____

I, _____ the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

Date Finalled: _____

Criteria	fw 2/17/13	res	Mr
Diagnostic Discrepancy			✓

Source: NCI Genomic Data Commons file 87836bb4-8cfc-426e-9170-46f7bf15c1f8 (TCGA-ND-A4WA.BEFD5412-08C0-4A14-82D4-9E1D71FD3EC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).